Somatic mutation profile of tumor specimen TCGA-BQ-5881-01A (aliquot TCGA-BQ-5881-01A-11D-1589-08) from TCGA case TCGA-BQ-5881, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.8 years (25,481 days).
Specimen TCGA-BQ-5881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baa75d37-6c6b-44a1-9923-3261f11302cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5881-11A (Solid Tissue Normal), aliquot TCGA-BQ-5881-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/879773eb-6f97-42f9-b134-ee357af8b044

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 27, Silent 6, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101229406, COSV67960170, COSV67961004; called by muse, mutect2
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGPS | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV51567210; called by muse, mutect2
- AKAP6 | c.3236T>A p.L1079Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55225082; called by muse, mutect2, varscan2
- ARAP1 | c.908T>C p.L303S (on ENST00000393609 / NM_001040118.2; = p.L58S on NM_015242.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61993397; called by muse, mutect2, varscan2
- BIRC6 | c.3144A>C p.E1048D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV70203574; called by muse, mutect2, varscan2
- CABIN1 | c.3315C>A p.D1105E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV54086503; called by muse, mutect2, varscan2
- CHAD | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV51973620; called by muse, mutect2, varscan2
- DAAM1 | c.926T>A p.L309Q | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV62838455; called by muse, mutect2, varscan2
- DDX53 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756147094, COSV60068983; called by muse, mutect2, varscan2
- INTS1 | c.1645A>G p.M549V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.385); catalogued as rs1030646527, COSV67178860; called by muse, mutect2, varscan2
- ITPRID2 | c.3296G>C p.G1099A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV57474843; called by muse, mutect2, varscan2
- MGA | c.3147T>A p.N1049K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.305); catalogued as COSV54959625; called by muse, mutect2, varscan2
- MYBPHL | c.542C>G p.T181R | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV64062679, COSV64062817; called by muse, mutect2, varscan2
- PDE6B | c.422A>C p.H141P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); catalogued as COSV55329017; called by muse, mutect2, varscan2
- PIK3CB | c.2021T>C p.L674P | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56688522; called by muse, mutect2, varscan2
- POMC | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.436); catalogued as rs146551109; called by muse, mutect2, varscan2
- SLC47A1 | c.355A>G p.S119G | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54502948; called by muse, mutect2, varscan2
- SMG5 | c.1271A>G p.K424R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs762509531, COSV62436772; called by muse, mutect2, varscan2
- SPIDR | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52385123; called by muse, mutect2, varscan2
- SSX2IP | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV60553886; called by muse, mutect2, varscan2
- TCAIM | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.878); catalogued as rs1396125213, COSV61240947, COSV61241898; called by muse, mutect2, varscan2
- TOP2B | c.3832T>G p.F1278V (on ENST00000264331 / NM_001330700.2; = p.F1273V on NM_001068.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV51975270; called by muse, mutect2
- TOP3B | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV64118666; called by muse, mutect2, varscan2
- VPS13C | c.10381A>T p.I3461F (on ENST00000644861 / NM_020821.3; = p.I3418F on NM_017684.5) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV51351133; called by muse, mutect2, varscan2
- ZBED9 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.915); catalogued as COSV71729651; called by muse, mutect2, varscan2
- ZFAND2B | c.446T>G p.I149S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV54697445, COSV54698660; called by muse, mutect2, varscan2
- ABHD16A | c.1402dup p.R468Pfs*20 | Frame Shift Ins (INS) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- ZNF559 | c.717del p.K239Nfs*22 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | called by mutect2, pindel, varscan2
- ACOT7 | c.441C>A p.I147= (on ENST00000377855 / NM_181864.3; = p.I137= on NM_007274.4) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV64114730; called by muse, mutect2, varscan2
- CCDC58 | c.30T>C p.C10= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV51659121; called by muse, mutect2, varscan2
- INTS5 | c.435T>C p.S145= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV57952863; called by muse, mutect2, varscan2
- RBPJL | c.528C>T p.R176= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs755955118, COSV59212719; called by muse, mutect2, varscan2
- SKA3 | c.984T>C p.T328= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV53436212; called by muse, mutect2, varscan2
- UGT1A3 | c.171G>A p.Q57= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs374045195; called by muse, mutect2, varscan2
